Somatic mutation profile of tumor specimen 0DLIFO from CCDI case PBBZDU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 24.8 years (9,059 days).
Specimen 0DLIFO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7984f2d4-4320-45da-a812-3b3322913ec1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLIF8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0df4255-e22b-4f1f-9f09-6b4f049cea6a

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 6, Splice Region 2, Splice Site 1, 3'Flank 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 351/965 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DIXDC1 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 172/738 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as COSV59462881; called by muse, mutect2, varscan2
- EPB42 | c.832+1G>T p.X278_splice (on ENST00000441366 / NM_001114134.2; = p.X308_splice on NM_000119.3) | Splice Site (SNP) | VAF 116/510 reads (23%) | catalogued as CS951400; called by muse, mutect2, varscan2
- GLS | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 61/1138 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.396); catalogued as rs1203764649; called by muse, mutect2
- MADD | c.4279G>A p.D1427N | Missense Mutation (SNP) | VAF 344/933 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.359); catalogued as rs773023506; called by muse, mutect2, varscan2
- CFAP91 | c.682+5G>C | Splice Region (SNP) | VAF 22/518 reads (4%) | called by muse, mutect2
- CHD9 | c.6233dup p.S2079Kfs*21 | Frame Shift Ins (INS) | VAF 138/1155 reads (12%) | called by mutect2, varscan2
- MUC19 | c.545A>T p.E182V | Missense Mutation (SNP) | VAF 145/747 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RAD18 | c.606G>A p.V202= | Splice Region (SNP) | VAF 46/622 reads (7%) | called by muse, mutect2
- TTLL10 | c.1253C>G p.T418S (on ENST00000379289 / NM_001130045.2; = p.T345S on NM_153254.3) | Missense Mutation (SNP) | VAF 168/909 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZC3H4 | c.3355G>A p.A1119T | Missense Mutation (SNP) | VAF 41/864 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.974); called by muse, mutect2
- ZNF565 | c.953C>T p.P318L (on ENST00000355114; = p.P278L on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 345/892 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- CASP5 | c.126A>G p.Q42= | Silent (SNP) | VAF 48/874 reads (5%) | called by muse, mutect2
- GAL3ST4 | c.1437G>A p.K479= | Silent (SNP) | VAF 235/616 reads (38%) | catalogued as rs1341133977; called by muse, mutect2, varscan2
- PKD1L1 | c.4344C>T p.V1448= | Silent (SNP) | VAF 32/891 reads (4%) | called by muse, mutect2
- PRSS21 | c.162G>A p.P54= | Silent (SNP) | VAF 119/593 reads (20%) | catalogued as rs769984449; called by muse, mutect2, varscan2
- RNF213 | c.9069T>C p.F3023= | Silent (SNP) | VAF 31/1259 reads (2%) | called by muse, mutect2
- SERPINE2 | c.30G>A p.L10= | Silent (SNP) | VAF 264/758 reads (35%) | called by muse, varscan2
- SDC4 | c.-10C>G | 5'UTR (SNP) | VAF 25/799 reads (3%) | catalogued as COSV65595738; called by muse, mutect2
- TUBGCP4 | chr15:43409142 del A | 3'Flank (DEL) | VAF 26/158 reads (16%) | called by mutect2, varscan2
